Somatic mutation profile of tumor specimen TCGA-VD-A8KG-01A (aliquot TCGA-VD-A8KG-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KG, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.7 years (17,417 days).
Specimen TCGA-VD-A8KG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df6d7592-47d6-4607-be11-599b02bd407a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KG-10A (Blood Derived Normal), aliquot TCGA-VD-A8KG-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b870009-f741-4fde-b734-887155a44c87

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CA2 | c.508-1G>A p.X170_splice | Splice Site (SNP) | VAF 93/151 reads (62%) | catalogued as CS920730; called by muse, mutect2, varscan2
- CD163 | c.996C>G p.S332R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.66); catalogued as COSV63132618; called by muse, mutect2, varscan2
- DVL2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs761312377, COSV99138281; called by muse, mutect2
- SPECC1 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs367591049; called by muse, mutect2
- ADGRL4 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DSCAM | c.378T>A p.Y126* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- FRMD7 | c.1377A>G p.I459M | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCEE | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2B2 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PADI2 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- SMC1A | c.3083T>C p.M1028T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- STAG1 | c.1928T>G p.L643* | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2, varscan2
- UGT2B17 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- DCDC2B | c.417G>A p.L139= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- ITGB8 | c.879T>C p.D293= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- MUSK | c.240T>C p.N80= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1203375135; called by muse, mutect2, varscan2
- PCDHA2 | c.363G>T p.V121= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as COSV65368609; called by muse, mutect2
